Surgical pathology report (de-identified scan), TCGA case TCGA-LN-A7HV, project TCGA-ESCA (Esophageal Carcinoma), tissue source site ILSBIO, specimen TCGA-LN-A7HV-01A (Primary Tumor).

[page 1 of 5]
IRB APPROVED

Clinical Case Report

(For Collection of Cancerous Tissue)

ICD-0-3

ID#:

Carcinoma, squamous cell
Site: Esophagus, middle third
15.4
JW 10/10/13

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married	VIETNAMESE	
☒ Male ☐ Female		☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
			13/8	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Trouble swallowing; vocal change.
Symptoms: Fever; weight loss
Clinical Findings:
Performance Scale (Karnofsky Score):
☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
ID#:

PAST MEDICAL HISTORY

Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY

Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses	# of Pregnancies
	Date of Last Menses	# of Live Births
	Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____	
		Hormone Replacement Therapy: _____

SOCIAL HISTORY

Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO		4 1/2 P/day	30 (yrs)	Still Smoke (yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		2 drinks/day	25 (yrs)	3 months ago (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY

Relative	Diagnosis	Age of Diagnosis

LAB DATA

Test	Result	Date	Test	Result	Date
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____	
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____	
B/T Cell Markers:					

[page 3 of 5]
ID#:

DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	A tumour was found in the oesophagus	
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Esophageal Cancer	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	Date of Diagnosis
T2 N0 M0 Stage: II A	

Treatment Information

SURGICAL TREATMENT			
Procedure		Date of Procedure	
Resection of the oesophagus			
Primary Tumor			
Organ	Detailed Location	Size	
oesophagus Tumor	Middle Third	4 x 2 x 1 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T2 N0 M0 Stage: II A			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
11 min		12 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
ESOPHAGEAL TUMOR	4 x 2 x 1cm	MIDDLE THIRD	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 2 N 0 M 0		Stage: IIA	
Notes:			

[page 5 of 5]
IRB APPROVED

Consolidated Pathology Diagnosis

ID#: _

Histological Pattern											
Cell Distribution			Structural Pattern								
	+	-		+	-		+	-		+	-
Diffuse		X	Streaming								
Mosaic	X		Storiform								
Necrosis	X		Fibrosis								
Lymphocytic Infiltration	X		Palisading								
Vascular Invasion		X	Cystic Degeneration								
Clusterized	X		Bleeding								
Alveolar Formation		X	Myxoid Change								
Indian File		X	Psammoma/Calcification								

Cellular Differentiation									
Squamous		Adenomatous		Sarcomatous		Lymphomatous			
+	-	+	-	+	-	+	-	+	-
Squamoid Cell	X	Glandular cell		Round Cell		Large Cell			
Spindle Cell	X	Cell Stratification		Fibroblast		Small Cell			
Keratin	X	Secretion		Osteoblast		RS Cell/RS Like			
Desmosome	X	Intracyt. Vacuole		Lipoblast		Inflam. Cell			
Pearl	X	Gland formation		Myoblast		Plasma Cell			

Cellular Differentiation: ☐ Well ☐ Moderate ☐ Poor

Nuclear Atypia:				
	0	I	II	III
Aniso Nucleosis		X		
Hyperchromatism			X	
Nucleolar Prominent		X		
Multinucleated Giant Cell			X	
Mitotic Activity		X		

Nuclear Grade: ☒ 0 ☒ I ☐ II ☐ III

D₁ 2% D₂ 35% D₃ 50% D₄ 50%

Necrosis 3%

Final Pathology Report

Histological Diagnosis: Squamous Cell Carcinoma Grade: 1

Comments:

Director, Research Pathology

Date

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

PATHOLOGISTS -

Source: NCI Genomic Data Commons file 5ab9ebf3-d915-405f-9db3-66fec778372d (TCGA-LN-A7HV.CF1C859A-A997-484A-8917-CAA0587781B8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).